TCGA case TCGA-FE-A3PA — Thyroid Carcinoma (TCGA-THCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland; Tissue source site: Ohio State University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/10bdafbb-831d-48b5-b9a3-ad374fc50235

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 16 years; Vital status: Alive.

Diagnoses (1)
1. Papillary carcinoma, follicular variant: ICD-O-3 morphology code: 8340/3; ICD-10 code: C73; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 16.6 years (6,068 days); Year of diagnosis: 2002; AJCC staging edition: 5th; AJCC pathologic T: T4; AJCC pathologic N: N0; AJCC pathologic M: M1; AJCC pathologic stage: Stage II; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R2; Days to last follow up: 3,235 days (8.9 years); Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Extrathyroid extension: Minimal (T3); Measurement unit: Centimeters; Tumor depth measurement: 3; Tumor length measurement: 4; Tumor width measurement: 3.
   Treatment given: Treatment type: Radiation, Systemic; Days to treatment start: 91 days; Days to treatment end: 91 days; Treatment dose: 217 mCi; Treatment outcome: Partial Response; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, Systemic; Days to treatment start: 378 days (1.0 years); Days to treatment end: 378 days (1.0 years); Treatment dose: 217 mCi; Treatment outcome: Complete Response; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Treatment dose: 434; Prescribed dose: 217; Pretreatment: Thyroxine Withdrawal.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Prescribed dose: 217; Pretreatment: Thyroxine Withdrawal; Timepoint category: First Treatment.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation, External Beam.

Follow-up (4 entries)
- Days to follow up: 2,872 days (7.9 years); Disease response: With Tumor.
- Days to follow up: 3,235 days (8.9 years); Disease response: Tumor Free.
- Disease response: Persistent Distant Metastasis; Timepoint: Within 3 Months of Surgery.
- Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Evidence of progression type: Convincing Image Source; Timepoint: Initial Diagnosis.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FE-A3PA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 70 mg.
  Slide TCGA-FE-A3PA-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-FE-A3PA-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FE-A3PA-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; History radiation exposure: No; Submitted tumor site: Thyroid; Histologic diagnosis: Thyroid Papillary Carcinoma - Follicular (>= 99% follicular patterned); Laterality: Left lobe; Lymph nodes preop imaging: No; Lymph nodes examined: No; Metastasis site: Lung.
- Neoplasm dimension: Tumor size width: 4.
- Metastatic neoplasm confirmed diagnosis method names: Metastatic diagnosis confirmed by: RAI-avid.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; I 131 radiation subsequent treatment: 217; Radiation therapy xrt method prep: Patient Did Not Receive External Radiation Therapy; Clinical status within 3 mths surgery: Persistent distant metastases; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,235 days; disease-specific survival: no event (censored), 3,235 days; progression-free interval: no event (censored), 3,235 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FE-A3PA-01A-12D-A21Y-01): tumor purity 0.81, ploidy 2, whole-genome doublings 0.
